Somatic mutation profile of tumor specimen C3L-00080-01 (aliquot CPT0001060005) from CPTAC case C3L-00080, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 58.0 years (21,194 days).
Specimen C3L-00080-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fee75b86-0e19-4427-92b3-cf65f2253dfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00080-31 (Blood Derived Normal), aliquot CPT0000020163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f9f4b6c-746f-4eba-8943-b58f208705e7

The open-access MAF lists 948 somatic variants for this specimen: 638 protein-altering or splice-affecting, 189 silent, 121 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 537, Silent 189, Nonsense Mutation 53, Intron 50, RNA 33, Frame Shift Del 22, 5'Flank 11, 3'UTR 11, Splice Site 11, 5'UTR 10, 3'Flank 6, In Frame Del 5.

Variants (750 of 948; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 240/407 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC136428.1 | c.247G>C p.V83L | Missense Mutation (SNP) | VAF 62/430 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV101434980; called by muse, mutect2, varscan2
- ADAMTSL1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV52822067; called by muse, mutect2, varscan2
- ADGRB3 | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs756724848; called by muse, mutect2, varscan2
- AFAP1 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 67/389 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs774337434, COSV61797596; called by muse, mutect2, varscan2
- ANKMY1 | c.1261G>T p.G421W | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs752676722; called by muse, mutect2, varscan2
- ANKRD30B | c.3268G>T p.E1090* | Nonsense Mutation (SNP) | VAF 47/83 reads (57%) | catalogued as COSV57702658; called by muse, mutect2, varscan2
- ANKRD30B | c.3407C>A p.T1136K | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV100271296; called by muse, varscan2
- ANO4 | c.841G>T p.G281C (on ENST00000392977 / NM_001286615.2; = p.G246C on NM_178826.4) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54585384; called by muse, mutect2, varscan2
- ANO4 | c.2548G>C p.G850R (on ENST00000392977 / NM_001286615.2; = p.G815R on NM_178826.4) | Missense Mutation (SNP) | VAF 155/390 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.709); catalogued as COSV100152420; called by muse, mutect2, varscan2
- APEX2 | c.1548G>T p.R516S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.433); catalogued as rs200234086; called by muse, varscan2
- ARMC3 | c.2542G>T p.V848L | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV53062458; called by muse, mutect2, varscan2
- ATM | c.2150G>C p.R717P | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs768874297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRNL1 | c.1523C>T p.T508I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs782690664; called by muse, varscan2
- BARHL2 | c.784C>A p.R262S | Missense Mutation (SNP) | VAF 125/402 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64981248; called by muse, mutect2, varscan2
- BICC1 | c.89G>C p.G30A | Missense Mutation (SNP) | VAF 51/325 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.006); catalogued as rs760166227; called by muse, mutect2, varscan2
- C6orf58 | c.384G>T p.W128C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61667279; called by muse, mutect2, varscan2
- CAPN12 | c.730-4C>T | Splice Region (SNP) | VAF 179/315 reads (57%) | catalogued as rs745818311; called by muse, mutect2, varscan2
- CATSPERD | c.1126C>A p.L376I | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100486691; called by muse, mutect2, varscan2
- CBLL2 | c.460C>A p.R154S | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.053); catalogued as COSV60369355; called by muse, mutect2, varscan2
- CCDC168 | c.14819C>T p.P4940L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.177); catalogued as rs964928703, COSV100487605; called by muse, mutect2, varscan2
- CCDC171 | c.1731G>T p.L577F | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901389; called by muse, varscan2
- CCDC197 | c.101C>G p.A34G | Missense Mutation (SNP) | VAF 161/376 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs747608390; called by muse, mutect2, varscan2
- CD1A | c.144G>T p.W48C | Missense Mutation (SNP) | VAF 102/355 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV56861818; called by muse, mutect2, varscan2
- CD1C | c.862G>T p.G288* | Nonsense Mutation (SNP) | VAF 55/203 reads (27%) | catalogued as COSV63808032; called by muse, mutect2, varscan2
- CD200R1L | c.628C>A p.H210N | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.498); catalogued as rs375349280; called by muse, mutect2, varscan2
- CD300C | c.478T>C p.W160R | Missense Mutation (SNP) | VAF 158/375 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs1229416870; called by muse, mutect2, varscan2
- CDH4 | c.1795G>A p.G599R | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777402708, COSV64643579; called by muse, mutect2, varscan2
- CEP295 | c.2705C>T p.S902F | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs781541375; called by muse, mutect2, varscan2
- CFAP299 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs963741195; called by muse, mutect2, varscan2
- CHD7 | c.5533G>T p.G1845W | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as CM1413033, COSV71111216, COSV71114308; called by muse, mutect2, varscan2
- CHST13 | c.380T>G p.L127R | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1039361311; called by muse, mutect2, varscan2
- CNST | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs868198156; called by muse, mutect2, varscan2
- CNTN2 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 120/329 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59352586; called by muse, mutect2, varscan2
- CNTNAP2 | c.3133G>T p.D1045Y | Missense Mutation (SNP) | VAF 142/355 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV62163800; called by muse, varscan2
- COL4A1 | c.1569G>T p.Q523H | Missense Mutation (SNP) | VAF 103/212 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV65433756; called by muse, mutect2, varscan2
- COLEC10 | c.691T>A p.Y231N | Missense Mutation (SNP) | VAF 110/348 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1333298370; called by muse, mutect2, varscan2
- COLGALT2 | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62298603; called by muse, mutect2, varscan2
- CSRNP2 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1400690969; called by muse, mutect2
- CTNND2 | c.2052C>A p.N684K | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV58935331; called by muse, mutect2, varscan2
- CYP11B1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 293/774 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV52824341; called by mutect2, varscan2
- DAAM1 | c.937A>G p.I313V | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV62839178; called by muse, mutect2, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 28/118 reads (24%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- DOHH | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 176/405 reads (43%) | catalogued as COSV99171100; called by muse, mutect2, varscan2
- DPEP1 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV99878742; called by muse, mutect2, varscan2
- DPP6 | c.2426G>T p.R809M (on ENST00000377770 / NM_001364500.2; = p.R747M on NM_001936.5) | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV59626032; called by muse, mutect2, varscan2
- DRD5 | c.356T>C p.F119S | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1329252530; called by muse, mutect2, varscan2
- DYSF | c.5518G>T p.V1840L | Missense Mutation (SNP) | VAF 204/551 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as CM1513878; called by muse, mutect2, varscan2
- EPHA4 | c.318G>T p.R106S | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV56039468; called by muse, mutect2, varscan2
- EPHB1 | c.386G>C p.W129S | Missense Mutation (SNP) | VAF 123/314 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101213243; called by muse, mutect2, varscan2
- EPPK1 | c.5860G>T p.A1954S | Missense Mutation (SNP) | VAF 160/426 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73261902; called by muse, mutect2, varscan2
- ERBB4 | c.1787G>T p.G596V | Missense Mutation (SNP) | VAF 167/587 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99038381; called by muse, mutect2, varscan2
- EVI5 | c.1993C>T p.R665* | Nonsense Mutation (SNP) | VAF 34/257 reads (13%) | catalogued as rs778007926; called by muse, mutect2, varscan2
- FAM47C | c.2111C>A p.P704Q | Missense Mutation (SNP) | VAF 182/335 reads (54%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.945); catalogued as COSV100792948; called by muse, mutect2, varscan2
- FBXO10 | c.2309G>T p.R770L | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.796); catalogued as COSV99446098; called by muse, mutect2, varscan2
- FCRLA | c.374G>T p.W125L (on ENST00000367959; = p.W102L on NM_032738.4) | Missense Mutation (SNP) | VAF 318/422 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879649489, COSV99030799; called by muse, mutect2, varscan2
- FLG | c.10933G>A p.G3645R | Missense Mutation (SNP) | VAF 97/906 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.741); catalogued as rs750903733, COSV100910450, COSV64241634; called by mutect2, varscan2
- FLG | c.5400C>G p.S1800R | Missense Mutation (SNP) | VAF 538/1147 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.624); catalogued as rs772604170; called by muse, mutect2, varscan2
- FLG | c.4951A>G p.R1651G | Missense Mutation (SNP) | VAF 145/892 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs770005572; called by muse, mutect2, varscan2
- FLYWCH1 | c.1579C>T p.R527W (on ENST00000253928 / NM_001308068.2; = p.R526W on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs746827704; called by muse, mutect2, varscan2
- FMN2 | c.3572C>A p.P1191H | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as rs761241566; called by muse, mutect2
- FOXK2 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.54); catalogued as rs763732479; called by muse, mutect2, varscan2
- FSHR | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 137/314 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371482817; called by muse, mutect2, varscan2
- FSIP2 | c.11588C>T p.P3863L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs529845185; called by muse, mutect2, varscan2
- FZD9 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs542138331, COSV60670627; called by muse, mutect2, varscan2
- GABRB3 | c.586G>T p.G196W | Missense Mutation (SNP) | VAF 95/624 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100159286, COSV54659883; called by muse, mutect2, varscan2
- GAS6 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as rs202234400; called by muse, mutect2, varscan2
- GFRA1 | c.527C>A p.T176N | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1323105417, COSV100816282, COSV62602714, COSV62608747; called by muse, mutect2, varscan2
- GLIPR1L2 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 51/702 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs1364707539, COSV57554722; called by muse, mutect2
- GMEB2 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 98/342 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs144182072; called by muse, mutect2, varscan2
- GOLIM4 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 92/390 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV58329480; called by muse, varscan2
- GORASP2 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 125/394 reads (32%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs773046298, COSV52201755; called by muse, mutect2, varscan2
- GRM2 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 126/310 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.056); catalogued as rs147501226, COSV56583864; called by muse, mutect2, varscan2
- GRM6 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 132/476 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778444272, COSV51432659; called by muse, mutect2, varscan2
- GTSF1 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 70/226 reads (31%) | catalogued as COSV59938254; called by muse, varscan2
- HLA-DMA | c.463C>G p.P155A | Missense Mutation (SNP) | VAF 65/389 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100877642; called by muse, mutect2, varscan2
- HYDIN | c.14630C>T p.S4877F | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs752031535, COSV101125107; called by muse, mutect2, varscan2
- IFNA1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs762951011; called by muse, mutect2, varscan2
- ILDR2 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs147213269; called by muse, mutect2, varscan2
- IRF4 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 93/326 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101110868, COSV66704597; called by muse, mutect2, varscan2
- ITGA9 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 265/573 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs760915010, COSV53236585; called by muse, mutect2, varscan2
- JPH2 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 97/353 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1326771127, COSV100881805; called by muse, mutect2, varscan2
- KCND2 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 64/415 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs561063026, COSV58568984; called by muse, mutect2, varscan2
- KCNK10 | c.1019C>A p.A340E | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375034474; called by muse, mutect2, varscan2
- KIAA1614 | c.2874C>A p.S958R | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV100851183; called by muse, mutect2, varscan2
- KRTAP21-2 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); catalogued as COSV100441181; called by muse, mutect2, varscan2
- LAMA2 | c.2050G>A p.V684I | Missense Mutation (SNP) | VAF 12/394 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV101370365; called by muse, mutect2
- LAMA2 | c.2567C>G p.S856C | Missense Mutation (SNP) | VAF 56/352 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV70352685; called by muse, mutect2, varscan2
- LARGE2 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148470206; called by muse, mutect2, varscan2
- LILRB1 | c.1286G>T p.G429V (on ENST00000427581; = p.G393V on NM_006669.6) | Missense Mutation (SNP) | VAF 143/384 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374192029, COSV100207636; called by muse, varscan2
- LMTK3 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.584); catalogued as rs761730706; called by muse, mutect2, varscan2
- LRRN2 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as rs558201537, COSV65784783; called by muse, mutect2, varscan2
- LRWD1 | c.416G>C p.R139P | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV99479335; called by muse, mutect2, varscan2
- MAGEC2 | c.314C>A p.S105Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); catalogued as COSV55999462; called by muse, mutect2, varscan2
- MDP1 | c.256C>A p.L86I | Missense Mutation (SNP) | VAF 121/266 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.725); catalogued as rs1216337619; called by muse, mutect2, varscan2
- MUC12 | c.15067C>A p.P5023T (on ENST00000379442; = p.P4880T on NM_001164462.1) | Missense Mutation (SNP) | VAF 140/345 reads (41%) | SIFT tolerated (0.86); catalogued as rs759181834; called by muse, mutect2, varscan2
- MYH2 | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV99821294; called by muse, mutect2, varscan2
- MYO5C | c.2492G>T p.R831L | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs764763786, COSV55911975; called by muse, mutect2, varscan2
- MYOCD | c.2813G>T p.W938L | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV58508054; called by muse, mutect2
- MYOCD | c.2814G>T p.W938C | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759797147; called by muse, mutect2, varscan2
- NAE1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs1243552694; called by muse, mutect2, varscan2
- NAV3 | c.4859C>T p.A1620V | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV57084636; called by muse, mutect2
- NCOR1 | c.7322G>C p.*2441Sext*15 | Nonstop Mutation (SNP) | VAF 88/275 reads (32%) | catalogued as COSV99252464; called by muse, mutect2, varscan2
- NETO1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 55/372 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs370635787; called by muse, mutect2, varscan2
- NLRP11 | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 109/210 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV64088248; called by muse, mutect2, varscan2
- NOD1 | c.1363G>C p.A455P | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs777205403; called by muse, mutect2, varscan2
- NPDC1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as rs778983633, COSV100064225; called by muse, varscan2
- NRXN3 | c.1492C>A p.R498S | Missense Mutation (SNP) | VAF 85/361 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55325456; called by muse, mutect2, varscan2
- OCA2 | c.2433G>T p.R811S | Missense Mutation (SNP) | VAF 131/427 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs779382711, CM085602; called by muse, mutect2, varscan2
- OCSTAMP | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 120/372 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as rs370553629; called by muse, mutect2, varscan2
- ODF3L2 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100205431; called by muse, mutect2, varscan2
- OR10K2 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 144/449 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV59220631; called by muse, mutect2, varscan2
- OR14C36 | c.642G>T p.R214S | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs895670394; called by muse, mutect2, varscan2
- OR2L5 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 42/128 reads (33%) | catalogued as rs757305763; called by muse, mutect2, varscan2
- OR2W1 | c.227G>T p.S76I | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV65851793; called by muse, mutect2, varscan2
- OR3A1 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 182/301 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV60162999; called by muse, mutect2, varscan2
- OR4A16 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59044626; called by muse, mutect2, varscan2
- OR4L1 | c.229A>T p.T77S | Missense Mutation (SNP) | VAF 117/286 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV59850686; called by muse, mutect2, varscan2
- OR52N5 | c.682A>C p.T228P | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs756690287; called by muse, mutect2, varscan2
- OR5B12 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100222486; called by muse, mutect2, varscan2
- OR5L2 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1244719905, COSV65724308; called by mutect2, varscan2
- OR6B2 | c.171G>T p.R57S | Missense Mutation (SNP) | VAF 51/434 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV99048231; called by muse, mutect2, varscan2
- OSBPL8 | c.2335G>A p.V779I | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.195); catalogued as rs367592972; called by muse, varscan2
- OTOG | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs372771088, COSV61130004; called by muse, mutect2, varscan2
- P3H3 | c.1617C>A p.S539R | Missense Mutation (SNP) | VAF 118/228 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51832733; called by muse, mutect2, varscan2
- PCDHA11 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.043); catalogued as COSV56536940; called by muse, mutect2, varscan2
- PCDHA8 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 91/626 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.036); catalogued as rs782077054, COSV65327429; called by muse, mutect2, varscan2
- PCDHB4 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 339/1078 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs782063409, COSV99522598; called by muse, mutect2, varscan2
- PCDHB9 | c.2177C>A p.S726* | Nonsense Mutation (SNP) | VAF 113/365 reads (31%) | catalogued as COSV53376085; called by muse, mutect2, varscan2
- PDE1A | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 49/164 reads (30%) | catalogued as COSV100112742; called by muse, mutect2, varscan2
- PDE1A | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.547); catalogued as rs761155078, COSV59516308; called by muse, varscan2
- PEG3 | c.1741C>G p.H581D | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99689186; called by muse, mutect2, varscan2
- PERM1 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as rs769281940; called by muse, mutect2, varscan2
- PEX5L | c.1176C>G p.N392K | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1400868305, COSV99829348; called by muse, mutect2
- PHLDB2 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV67315209, COSV67316228; called by muse, mutect2, varscan2
- PI4KB | c.710G>A p.R237Q (on ENST00000368873 / NM_001369623.1; = p.R249Q on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as rs779289312; called by muse, mutect2, varscan2
- PIGK | c.847A>T p.T283S | Missense Mutation (SNP) | VAF 83/265 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.403); catalogued as rs770702172; called by muse, mutect2, varscan2
- PIGU | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs922546544; called by muse, mutect2, varscan2
- POM121L12 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 122/425 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs371219263; called by muse, mutect2, varscan2
- POM121L12 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 122/424 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.372); catalogued as COSV68692885; called by muse, mutect2, varscan2
- POTEC | c.662G>A p.C221Y | Missense Mutation (SNP) | VAF 38/357 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs556119204; called by muse, mutect2, varscan2
- PTGER4 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs199975495, COSV100201739, COSV56721847; called by muse, mutect2, varscan2
- PTH | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs770840441; called by muse, varscan2
- PYHIN1 | c.542C>A p.T181N | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.548); catalogued as rs1010335372; called by muse, mutect2, varscan2
- RBFOX1 | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.88); catalogued as rs760565499; called by muse, mutect2, varscan2
- REG3A | c.70G>T p.V24F | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV59410545; called by muse, mutect2, varscan2
- RGS3 | c.1045G>T p.V349L (on ENST00000350696 / NM_001282923.2; = p.V237L on NM_017790.4) | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100464632; called by muse, mutect2, varscan2
- RGS7 | c.602G>T p.R201M | Missense Mutation (SNP) | VAF 154/529 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58557182; called by muse, mutect2, varscan2
- RGS9 | c.1102A>G p.I368V | Missense Mutation (SNP) | VAF 122/674 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1393029319; called by muse, mutect2, varscan2
- RIMS2 | c.2563C>A p.H855N (on ENST00000666250 / NM_001348490.2; = p.H663N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51719862; called by muse, mutect2, varscan2
- RNF157 | c.1327G>A p.V443M | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.048); catalogued as rs201495655, COSV53942053; called by muse, mutect2, varscan2
- RSPH14 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369415088; called by muse, mutect2, varscan2
- RYR2 | c.13600C>A p.P4534T | Missense Mutation (SNP) | VAF 89/268 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs199624074, COSV100772132, COSV63681516; called by muse, mutect2, varscan2
- RYR3 | c.11159G>C p.R3720P (on ENST00000389232; = p.R3721P on NM_001036.6) | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.333); catalogued as rs765197731; called by muse, mutect2, varscan2
- SAGE1 | c.1896G>C p.E632D | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV61014333; called by muse, mutect2, varscan2
- SDK2 | c.1144G>T p.A382S | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV66190160; called by muse, mutect2, varscan2
- SEMA6C | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 48/391 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs754066193, COSV58999779; called by muse, mutect2, varscan2
- SLC26A1 | c.146T>A p.L49Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1553915787; called by muse, mutect2, varscan2
- SLC28A1 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs113577701; called by muse, mutect2, varscan2
- SLC29A4 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.082); catalogued as rs372832360; called by muse, mutect2, varscan2
- SLC2A4 | c.842G>T p.S281I | Missense Mutation (SNP) | VAF 306/495 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs1272174457; called by muse, mutect2, varscan2
- SNTG1 | c.566C>G p.S189W | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52456337; called by muse, mutect2, varscan2
- SNX6 | c.230C>T p.S77L (on ENST00000652385; = p.S65L on NM_152233.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as COSV61917457; called by muse, mutect2, varscan2
- SORBS2 | c.470G>A p.S157N (on ENST00000284776 / NM_021069.5; = p.S203N on NM_003603.6) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs776319003; called by muse, mutect2, varscan2
- SPAM1 | c.159G>T p.W53C | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56141553; called by muse, mutect2, varscan2
- SPHKAP | c.2650C>A p.Q884K | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as COSV100764208; called by muse, mutect2, varscan2
- SUN5 | c.675C>A p.Y225* | Nonsense Mutation (SNP) | VAF 96/321 reads (30%) | catalogued as rs774107230; called by muse, mutect2, varscan2
- SYNE1 | c.3616G>C p.E1206Q (on ENST00000367255 / NM_182961.4; = p.E1213Q on NM_033071.3) | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.424); catalogued as COSV99549557; called by muse, mutect2, varscan2
- TENM2 | c.4423G>T p.E1475* (on ENST00000518659 / NM_001122679.2; = p.E1236* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 112/272 reads (41%) | catalogued as COSV69141867; called by muse, mutect2, varscan2
- TMEM151A | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 143/386 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59174772; called by muse, mutect2, varscan2
- TMEM178A | c.50G>C p.C17S | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV56142273; called by muse, mutect2, varscan2
- TNFRSF17 | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.883); catalogued as COSV99273244; called by muse, varscan2
- TOPORS | c.2591G>T p.S864I | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62116117; called by muse, mutect2, varscan2
- TPRA1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 129/342 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs778552939; called by muse, mutect2, varscan2
- TRIM49C | c.87C>A p.D29E | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.95); catalogued as COSV99081627; called by mutect2, varscan2
- TRIM58 | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV100825286, COSV63572111; called by muse, mutect2, varscan2
- TROAP | c.1219G>T p.G407C | Missense Mutation (SNP) | VAF 86/322 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1341245167; called by muse, mutect2, varscan2
- TRRAP | c.9076A>T p.S3026C (on ENST00000359863 / NM_001244580.1; = p.S2997C on NM_003496.3) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV62853129; called by muse, mutect2, varscan2
- TSHZ3 | c.1840G>T p.V614L | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV53666219; called by muse, mutect2, varscan2
- TTLL10 | c.1893C>A p.S631R | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.077); catalogued as rs907856399; called by muse, mutect2, varscan2
- ULK4 | c.2980T>A p.Y994N | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV57226462; called by muse, mutect2, varscan2
- URB2 | c.3239C>T p.A1080V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs1474694785, COSV50981600; called by muse, mutect2, varscan2
- USH2A | c.13586C>A p.P4529H | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56409306; called by muse, mutect2, varscan2
- USH2A | c.11453C>A p.P3818H | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.964); catalogued as COSV56364424; called by muse, varscan2
- USH2A | c.3445G>C p.E1149Q | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs759379256; called by muse, varscan2
- USH2A | c.3404G>A p.R1135K | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs779191150, CD149973; called by muse, varscan2
- USO1 | c.2416G>T p.V806L | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs768546206; called by muse, mutect2, varscan2
- VCX3A | c.555T>A p.S185R | Missense Mutation (SNP) | VAF 176/356 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV66910595; called by muse, varscan2
- VIT | c.1604G>T p.G535V (on ENST00000389975 / NM_001177969.1; = p.G550V on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64898741; called by muse, mutect2, varscan2
- WDR47 | c.1159A>G p.I387V (on ENST00000369962 / NM_001142551.2; = p.I388V on NM_014969.5) | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs773950461; called by muse, varscan2
- ZFC3H1 | c.4760G>T p.C1587F | Missense Mutation (SNP) | VAF 72/362 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101110624; called by muse, mutect2, varscan2
- ZFYVE26 | c.2371A>G p.T791A | Missense Mutation (SNP) | VAF 70/630 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.615); catalogued as COSV100720266; called by muse, mutect2, varscan2
- ZIC3 | c.1157A>T p.K386M | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54976993, COSV54977617; called by muse, mutect2, varscan2
- ZNF100 | c.1144T>G p.F382V | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1568286525; called by muse, mutect2, varscan2
- ZNF318 | c.3809C>A p.S1270* | Nonsense Mutation (SNP) | VAF 38/230 reads (17%) | catalogued as COSV100546438; called by muse, mutect2, varscan2
- ZNF362 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV65031502; called by mutect2, varscan2
- ZNF385D | c.220del p.H74Tfs*14 | Frame Shift Del (DEL) | VAF 39/96 reads (41%) | catalogued as COSV55758010; called by mutect2, pindel, varscan2
- ZNF536 | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs775852776, COSV100834571; called by muse, mutect2, varscan2
- ZNF536 | c.3652G>A p.V1218I | Missense Mutation (SNP) | VAF 109/185 reads (59%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs138308449; called by muse, mutect2, varscan2
- ZPLD1 | c.838del p.R280Dfs*3 (on ENST00000466937 / NM_001329788.1; = p.R296Dfs*3 on NM_175056.2) | Frame Shift Del (DEL) | VAF 61/196 reads (31%) | catalogued as COSV60352581; called by mutect2, pindel, varscan2
- ABCB11 | c.2389G>T p.G797C | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ABCC11 | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- AC004997.1 | c.1024C>G p.P342A | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.88); called by muse, mutect2, varscan2
- AC009779.3 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 172/580 reads (30%) | called by muse, mutect2, varscan2
- ACAP1 | c.595del p.Q199Rfs*12 | Frame Shift Del (DEL) | VAF 69/240 reads (29%) | called by mutect2, pindel, varscan2
- ACRV1 | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 122/374 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ACSM1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM20 | c.614A>T p.H205L | Missense Mutation (SNP) | VAF 81/379 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ADAMTS17 | c.2717C>A p.P906Q | Missense Mutation (SNP) | VAF 73/314 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS19 | c.2189C>G p.A730G | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.772A>T p.T258S | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADGB | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- AGO2 | c.2476G>T p.E826* | Nonsense Mutation (SNP) | VAF 84/190 reads (44%) | called by muse, varscan2
- AHCYL2 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK2 | c.13189A>C p.K4397Q | Missense Mutation (SNP) | VAF 76/708 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- AKAIN1 | c.151A>T p.N51Y | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ALPK2 | c.4612A>T p.T1538S | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ALS2CL | c.2749G>A p.G917S | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANAPC1 | c.5721del p.S1908Afs*14 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | called by mutect2, varscan2
- ANAPC1 | c.5720G>C p.G1907A | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); called by mutect2, varscan2
- ANKRD30B | c.3517A>C p.T1173P | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, varscan2
- ANKRD33B | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 138/241 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- ANKRD46 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 62/196 reads (32%) | PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ANOS1 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 101/213 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- APOB | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 104/227 reads (46%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.6105G>T p.Q2035H | Missense Mutation (SNP) | VAF 99/352 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ARHGAP11A | c.474G>C p.L158F | Missense Mutation (SNP) | VAF 113/448 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP9 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 86/272 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP9 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 106/290 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF6 | c.1541G>T p.C514F | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARL14EP | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ARMC4 | c.2246T>C p.V749A | Missense Mutation (SNP) | VAF 55/357 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- ARSI | c.477del p.T160Pfs*108 | Frame Shift Del (DEL) | VAF 246/528 reads (47%) | called by mutect2, pindel, varscan2
- ASB7 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 120/293 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ASCL3 | c.230C>G p.P77R | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ASPM | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 116/351 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ASTN1 | c.971C>A p.T324N | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ASTN2 | c.1230G>C p.Q410H (on ENST00000313400 / NM_001365069.1; = p.Q359H on NM_014010.5) | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ASXL3 | c.1235C>G p.A412G | Missense Mutation (SNP) | VAF 42/1354 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.023); called by muse, mutect2
- ATG2A | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 106/261 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATG4A | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ATP9B | c.2617+1G>T p.X873_splice | Splice Site (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- BCHE | c.291A>G p.I97M | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- BCR | c.812G>T p.W271L | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- BDKRB1 | c.721_738del p.G241_S246del | In Frame Del (DEL) | VAF 49/313 reads (16%) | called by mutect2, pindel
- BPIFC | c.835T>A p.Y279N | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BRIP1 | c.1908G>T p.E636D | Missense Mutation (SNP) | VAF 89/176 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRWD1 | c.165G>T p.E55D | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- C1QB | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C1orf94 | c.724C>T p.Q242* (on ENST00000488417 / NM_001134734.2; = p.Q52* on NM_032884.5) | Nonsense Mutation (SNP) | VAF 37/178 reads (21%) | called by muse, mutect2, varscan2
- C2CD4C | c.1088T>A p.V363E | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- C2orf16 | c.2651T>A p.L884Q | Missense Mutation (SNP) | VAF 43/487 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C2orf78 | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- C7orf33 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- CACNA1E | c.871C>A p.Q291K | Missense Mutation (SNP) | VAF 78/361 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CARD16 | c.403A>G p.N135D | Missense Mutation (SNP) | VAF 80/403 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- CATSPER1 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 244/639 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.019); called by mutect2, varscan2
- CATSPERB | c.28G>T p.V10F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- CBLB | c.876G>T p.L292F | Missense Mutation (SNP) | VAF 79/583 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CBY2 | c.426del p.Q143Sfs*87 | Frame Shift Del (DEL) | VAF 141/361 reads (39%) | called by mutect2, pindel, varscan2
- CCDC58 | c.71G>A p.R24K | Missense Mutation (SNP) | VAF 100/234 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC60 | c.455C>G p.P152R | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD109 | c.2622G>C p.Q874H | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, varscan2
- CDH2 | c.915G>T p.R305S | Missense Mutation (SNP) | VAF 53/1076 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.441); called by muse, mutect2
- CDK6 | c.277A>C p.K93Q | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CDRT15 | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.607); called by muse, varscan2
- CENPC | c.1345A>T p.I449F | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CENPQ | c.547_551del p.I183Dfs*5 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- CEP104 | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CEP97 | c.2177A>T p.E726V | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- CHRDL2 | c.1134G>C p.L378F (on ENST00000376332 / NM_001304415.1; = p.D397H on NM_015424.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.624); called by muse, varscan2
- CHRNA10 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 41/195 reads (21%) | called by muse, mutect2, varscan2
- CIART | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CIPC | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CLCN3 | c.456G>T p.W152C | Missense Mutation (SNP) | VAF 111/260 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLCNKA | c.1978T>A p.S660T | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CLIC3 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- CLTCL1 | c.4075G>T p.A1359S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CMKLR1 | c.998_999del p.R333Pfs*7 (on ENST00000312143 / NM_001142344.2; = p.R331Pfs*7 on NM_004072.3) | Frame Shift Del (DEL) | VAF 27/271 reads (10%) | called by mutect2, pindel, varscan2
- CNDP1 | c.167G>T p.W56L | Missense Mutation (SNP) | VAF 65/442 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL11A1 | c.2657G>T p.G886V | Missense Mutation (SNP) | VAF 151/347 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL5A3 | c.3235G>A p.G1079R | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A6 | c.2792C>T p.A931V | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COQ7 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPM | c.1288_1308del p.F431_L437del | In Frame Del (DEL) | VAF 50/266 reads (19%) | called by mutect2, pindel, varscan2
- CPNE3 | c.634-2A>G p.X212_splice | Splice Site (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- CSF2RB | c.1355T>A p.L452H | Missense Mutation (SNP) | VAF 92/430 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- CSMD1 | c.707G>C p.W236S | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSN3 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 78/375 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- CST9 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- CUX2 | c.440A>G p.Q147R | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CUX2 | c.2085C>A p.S695R | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DACT3 | c.449G>C p.G150A | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DARS1 | c.428_431del p.Y143* | Frame Shift Del (DEL) | VAF 46/159 reads (29%) | called by mutect2, pindel, varscan2
- DCSTAMP | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX39B | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- DDX41 | c.542A>T p.K181M | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- DENND1A | c.663G>T p.M221I | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- DHX34 | c.618T>G p.H206Q | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- DHX9 | c.2978C>G p.S993C | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DIDO1 | c.4174G>T p.D1392Y | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- DIRAS1 | c.559_576del p.R187_K192del | In Frame Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- DISC1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 137/565 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLG5 | c.3370G>T p.A1124S | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH11 | c.9271G>T p.E3091* | Nonsense Mutation (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- DNAH3 | c.1979C>A p.P660H | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- DPYSL2 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- DRD2 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DRD3 | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 142/452 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- DSCAM | c.4316A>T p.E1439V | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DSEL | c.587A>T p.N196I | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- DST | c.13088A>C p.K4363T (on ENST00000361203 / NM_001374722.1; = p.K1951T on NM_015548.5) | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- EIF2AK4 | c.3945G>C p.L1315F | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- EIF3H | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 140/400 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ELOVL2 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- EML1 | c.1759G>T p.A587S | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- EPHA6 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EPHA6 | c.1463G>T p.G488V | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA6 | c.2808G>T p.W936C | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPHX4 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ERN2 | c.860C>A p.T287K | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ESYT3 | c.1071G>C p.W357C | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXOC6 | c.427A>G p.S143G | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FAM181A | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 134/513 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- FAM229B | c.16G>T p.G6* | Nonsense Mutation (SNP) | VAF 64/127 reads (50%) | called by muse, mutect2, varscan2
- FAM71E2 | c.2125G>T p.E709* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- FAM90A1 | c.940C>A p.Q314K | Missense Mutation (SNP) | VAF 273/938 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- FBN1 | c.6652G>T p.A2218S | Missense Mutation (SNP) | VAF 160/426 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FBN2 | c.6395C>T p.P2132L | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO25 | c.386T>C p.L129S (on ENST00000382824 / NM_183421.2; = p.L62S on NM_012173.3) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FER1L6 | c.1835A>T p.E612V | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- FFAR1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- FGF13 | c.48G>A p.K16= | Splice Region (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- FGFR4 | c.1945G>T p.G649C | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLNC | c.2008-3C>A | Splice Region (SNP) | VAF 89/374 reads (24%) | called by muse, mutect2, varscan2
- FMO3 | c.1342C>G p.P448A | Missense Mutation (SNP) | VAF 104/318 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- FN1 | c.6092G>T p.G2031V | Missense Mutation (SNP) | VAF 120/463 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- FOXC2 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXK1 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FREM1 | c.4039G>T p.D1347Y | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FSHR | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 141/322 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FSIP2 | c.9655A>T p.K3219* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- FSIP2 | c.20162C>A p.T6721N | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FZD8 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- GAA | c.2587G>T p.E863* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- GABRA1 | c.1319C>A p.A440D | Missense Mutation (SNP) | VAF 94/228 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GABRA3 | c.1106G>A p.W369* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- GABRB2 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 138/404 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GALM | c.233G>T p.R78M | Missense Mutation (SNP) | VAF 157/322 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT1 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2
- GALNT11 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GATA4 | c.47dup p.A17Cfs*193 | Frame Shift Ins (INS) | VAF 124/335 reads (37%) | called by mutect2, pindel, varscan2
- GDF6 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 87/258 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GFRA3 | c.725C>G p.P242R | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GJD2 | c.245A>G p.Q82R | Missense Mutation (SNP) | VAF 62/329 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GLG1 | c.1674G>T p.K558N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GLIPR2 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLMN | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.054); called by mutect2, varscan2
- GNG11 | c.211G>T p.V71F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GOLGA8T | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GP2 | c.1302G>C p.E434D (on ENST00000381362 / NM_001007240.3; = p.E431D on NM_001502.4) | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GPR137 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR33 | c.965T>G p.F322C | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- GPR50 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- GRAMD1B | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIN2B | c.2792T>A p.V931D | Missense Mutation (SNP) | VAF 170/370 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GRM1 | c.3493C>A p.P1165T | Missense Mutation (SNP) | VAF 64/450 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- GTSE1 | c.1343G>T p.S448I | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- GYS1 | c.960G>C p.L320F | Missense Mutation (SNP) | VAF 26/532 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- H2BW2 | c.92C>A p.T31K | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.46); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- HARS2 | c.460G>T p.G154* | Nonsense Mutation (SNP) | VAF 195/649 reads (30%) | called by muse, mutect2, varscan2
- HGF | c.1040+1G>T p.X347_splice | Splice Site (SNP) | VAF 34/296 reads (11%) | called by muse, mutect2
- HGF | c.1039A>C p.K347Q | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HOXA3 | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HOXC13 | c.673A>T p.S225C | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- HR | c.2755G>T p.E919* | Nonsense Mutation (SNP) | VAF 20/422 reads (5%) | called by muse, mutect2
- HTR1F | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- HUNK | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 35/186 reads (19%) | called by muse, mutect2, varscan2
- HYDIN | c.9798C>A p.F3266L | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGDCC4 | c.2824A>T p.T942S | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- IGHM | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 198/767 reads (26%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- IGHMBP2 | c.1883A>C p.E628A | Missense Mutation (SNP) | VAF 300/618 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IKBIP | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 99/291 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- IKBKB | c.1941G>T p.Q647H | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- INCENP | c.2506G>T p.A836S (on ENST00000394818 / NM_001040694.2; = p.A832S on NM_020238.3) | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- INPP5J | c.1897C>T p.Q633* (on ENST00000331075 / NM_001284285.2; = p.Q265* on NM_001002837.2) | Nonsense Mutation (SNP) | VAF 30/137 reads (22%) | called by muse, mutect2, varscan2
- INSRR | c.3796del p.R1266Gfs*112 | Frame Shift Del (DEL) | VAF 230/790 reads (29%) | called by mutect2, pindel, varscan2
- ITGA4 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITIH3 | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KANK2 | c.1697G>T p.R566L (on ENST00000586659 / NM_001379562.1; = p.R574L on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KCNA4 | c.1162G>T p.V388F | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- KCNH6 | c.2202C>A p.H734Q | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KCNMA1 | c.2807C>T p.T936I (on ENST00000286628 / NM_001161352.2; = p.T878I on NM_002247.4) | Missense Mutation (SNP) | VAF 58/322 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- KCNRG | c.551G>C p.S184T | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.024); called by muse, mutect2
- KCNT2 | c.2633T>C p.F878S | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- KDR | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- KDR | c.2827G>T p.A943S | Missense Mutation (SNP) | VAF 26/493 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- KIF3B | c.1660G>T p.E554* | Nonsense Mutation (SNP) | VAF 95/285 reads (33%) | called by muse, mutect2, varscan2
- KIF4B | c.569G>T p.C190F | Missense Mutation (SNP) | VAF 286/667 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- KPNA3 | c.1165G>T p.A389S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT1 | c.1114T>G p.L372V | Missense Mutation (SNP) | VAF 45/438 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, varscan2
- KRTAP20-3 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- KRTAP4-2 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 71/550 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- L2HGDH | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 146/367 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- L3MBTL3 | c.1699G>T p.G567C | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- L3MBTL3 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA1 | c.8665G>A p.A2889T | Missense Mutation (SNP) | VAF 94/511 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- LAMA5 | c.9273del p.G3093Afs*14 | Frame Shift Del (DEL) | VAF 80/354 reads (23%) | called by mutect2, pindel, varscan2
- LAMA5 | c.6035G>T p.G2012V | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LEFTY2 | c.220_221insA p.R74Qfs*179 | Frame Shift Ins (INS) | VAF 93/354 reads (26%) | called by mutect2, pindel, varscan2
- LGALS16 | c.216G>T p.W72C | Missense Mutation (SNP) | VAF 237/447 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMO2 | c.445T>A p.Y149N (on ENST00000395833 / NM_001142315.2; = p.Y218N on NM_005574.4) | Missense Mutation (SNP) | VAF 88/196 reads (45%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- LMX1B | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- LOXHD1 | c.4301del p.D1434Afs*8 | Frame Shift Del (DEL) | VAF 49/253 reads (19%) | called by mutect2, pindel, varscan2
- LOXHD1 | c.121A>T p.K41* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- LPA | c.6057G>T p.K2019N | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRIT2 | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRP1B | c.11674A>T p.I3892F | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- LRP2 | c.10327A>T p.T3443S | Missense Mutation (SNP) | VAF 160/558 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LRP2 | c.9204C>A p.C3068* | Nonsense Mutation (SNP) | VAF 140/498 reads (28%) | called by muse, mutect2, varscan2
- LRRC71 | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 88/301 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- LRRC8C | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRK2 | c.7354T>C p.C2452R | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- LZTS1 | c.1040A>T p.Q347L | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MAMLD1 | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPKBP1 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, varscan2
- MCM10 | c.1099G>T p.E367* (on ENST00000484800 / NM_182751.3; = p.E366* on NM_018518.5) | Nonsense Mutation (SNP) | VAF 31/138 reads (22%) | called by muse, mutect2, varscan2
- MELTF | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MMP2 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- MORC1 | c.1196G>C p.G399A | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MORC1 | c.711C>A p.F237L | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MPDZ | c.1754G>T p.G585V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPEG1 | c.1343T>C p.V448A | Missense Mutation (SNP) | VAF 42/409 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MPP6 | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- MS4A4E | c.841del p.D281Tfs*2 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- MTHFD1L | c.2194G>T p.G732C | Missense Mutation (SNP) | VAF 56/260 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- MTMR14 | c.702C>G p.D234E | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTTP | c.1648A>T p.N550Y | Missense Mutation (SNP) | VAF 136/288 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- MUC17 | c.13333T>A p.F4445I | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MUC5AC | c.15059T>A p.V5020E | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- MUTYH | c.863C>A p.T288N | Missense Mutation (SNP) | VAF 121/703 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MYH4 | c.2935-2A>C p.X979_splice | Splice Site (SNP) | VAF 93/264 reads (35%) | called by muse, mutect2, varscan2
- MYH7 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 291/716 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MYH8 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAV3 | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBPF14 | c.8657G>C p.R2886T | Missense Mutation (SNP) | VAF 102/560 reads (18%) | SIFT tolerated, low confidence (0.24); called by muse, mutect2, varscan2
- NCKAP5L | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 94/284 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NFATC1 | c.1480G>T p.V494L | Missense Mutation (SNP) | VAF 79/441 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- NIPBL | c.8252C>G p.A2751G | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NKD1 | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- NLGN1 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 41/315 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP5 | c.3239G>T p.G1080V | Missense Mutation (SNP) | VAF 99/214 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NPAS3 | c.2526C>A p.S842R (on ENST00000356141 / NM_001164749.2; = p.S810R on NM_022123.3) | Missense Mutation (SNP) | VAF 327/759 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NPAS4 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 195/503 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NPEPPS | c.1095+1del | Frame Shift Del (DEL) | VAF 31/127 reads (24%) | called by mutect2, pindel*
- NPIPB2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- NPIPB5 | c.1031A>T p.E344V | Missense Mutation (SNP) | VAF 217/1242 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- NPR1 | c.1601G>A p.S534N | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.271); called by muse, mutect2
- NRXN1 | c.1796C>A p.T599N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, varscan2
- OBSL1 | c.2075G>T p.G692V | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OLFM2 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 137/320 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OMP | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR14A16 | c.293dup p.V99Gfs*21 | Frame Shift Ins (INS) | VAF 75/237 reads (32%) | called by mutect2, pindel, varscan2
- OR14C36 | c.165G>T p.M55I | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2A12 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 67/446 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- OR2AK2 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- OR2G3 | c.103T>A p.Y35N | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2M7 | c.738G>T p.M246I | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR3A2 | c.205T>C p.Y69H | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4A47 | c.616A>T p.T206S | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR4C15 | c.227A>T p.Q76L (on ENST00000314644; = p.Q22L on NM_001001920.2) | Missense Mutation (SNP) | VAF 79/245 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- OR4K13 | c.278C>A p.S93* | Nonsense Mutation (SNP) | VAF 160/363 reads (44%) | called by muse, mutect2, varscan2
- OR51F2 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- OR5W2 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- OR6B3 | c.171G>T p.R57S | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.146); called by muse, varscan2
- OR6Q1 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.031); called by mutect2, varscan2
- OSBPL3 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- OTOA | c.571T>G p.F191V | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- OTOF | c.5654G>C p.R1885P (on ENST00000272371 / NM_194248.3; = p.R1118P on NM_004802.4) | Missense Mutation (SNP) | VAF 97/448 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOG | c.8395G>T p.V2799L | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- P2RY10 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 103/176 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PADI6 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 64/412 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PARN | c.1549C>G p.Q517E | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PAX8 | c.1190-5A>T | Splice Region (SNP) | VAF 66/226 reads (29%) | called by muse, mutect2, varscan2
- PCDH11X | c.2294T>A p.V765D | Missense Mutation (SNP) | VAF 141/245 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- PCDHA10 | c.1816C>A p.L606M | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCDHA10 | c.2030C>A p.A677D | Missense Mutation (SNP) | VAF 86/258 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- PCDHA3 | c.1002C>A p.C334* | Nonsense Mutation (SNP) | VAF 140/470 reads (30%) | called by muse, mutect2, varscan2
- PCDHA3 | c.2252C>A p.S751* | Nonsense Mutation (SNP) | VAF 102/352 reads (29%) | called by muse, mutect2, varscan2
- PCDHB3 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- PCDHGA6 | c.2260del p.S754Pfs*15 | Frame Shift Del (DEL) | VAF 137/547 reads (25%) | called by mutect2, pindel, varscan2
- PCDHGB5 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 70/552 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCNX2 | c.4293C>A p.H1431Q | Missense Mutation (SNP) | VAF 136/427 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEG3 | c.4119A>T p.E1373D | Missense Mutation (SNP) | VAF 132/350 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PHKA2 | c.1429C>G p.R477G | Missense Mutation (SNP) | VAF 132/251 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- PLCH1 | c.4391G>T p.S1464I (on ENST00000340059 / NM_001130960.2; = p.S1456I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/292 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PLEKHH1 | c.3535C>A p.R1179S | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PLPPR4 | c.2173G>C p.D725H | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PLXNA2 | c.2525_2533dup p.S842_P844dup | In Frame Ins (INS) | VAF 45/191 reads (24%) | called by mutect2, varscan2
- PMPCA | c.413del p.G138Vfs*39 | Frame Shift Del (DEL) | VAF 27/162 reads (17%) | called by mutect2, pindel, varscan2
- PNCK | c.415-2A>T p.X139_splice (on ENST00000340888 / NM_001366975.1; = p.X222_splice on NM_001039582.3) | Splice Site (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2
- POTEA | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- POU1F1 | c.58T>A p.S20T | Missense Mutation (SNP) | VAF 136/299 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PPFIA2 | c.1800G>C p.W600C | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- PRAG1 | c.3340G>T p.E1114* | Nonsense Mutation (SNP) | VAF 15/193 reads (8%) | called by muse, mutect2
- PRAMEF14 | c.464T>G p.L155R | Missense Mutation (SNP) | VAF 77/421 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRAMEF6 | c.539T>A p.L180Q | Missense Mutation (SNP) | VAF 46/445 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRDM10 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PRUNE2 | c.6701G>T p.S2234I | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- PTMA | c.154G>A p.E52K (on ENST00000341369 / NM_001099285.2; = p.E51K on NM_002823.5) | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRB | c.5360G>T p.W1787L | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASA1 | c.3033_3041del p.L1012_N1014del | In Frame Del (DEL) | VAF 99/258 reads (38%) | called by mutect2, pindel, varscan2
- RBP3 | c.2441A>T p.D814V | Missense Mutation (SNP) | VAF 210/656 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RDH8 | c.838C>T p.R280C (on ENST00000651512; = p.R260C on NM_015725.4) | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- REG3A | c.309G>T p.W103C | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIBC2 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- RIMS2 | c.3107C>G p.S1036* (on ENST00000666250 / NM_001348490.2; = p.S844* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 46/202 reads (23%) | called by muse, mutect2, varscan2
- RNASE7 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 101/215 reads (47%) | called by muse, mutect2, varscan2
- RPAP1 | c.4136A>T p.Q1379L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2
- RSU1 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 83/296 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RTN1 | c.1276G>C p.A426P | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- RTP1 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2
- RUBCN | c.889A>T p.S297C | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- RUNDC3B | c.1371C>G p.Y457* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- RYK | c.1397A>T p.H466L (on ENST00000620660 / NM_001005861.2; = p.H463L on NM_002958.4) | Missense Mutation (SNP) | VAF 149/540 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.6634A>T p.K2212* | Nonsense Mutation (SNP) | VAF 38/155 reads (25%) | called by muse, mutect2, varscan2
- RYR3 | c.4829T>A p.L1610H | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR3 | c.13459T>G p.S4487A (on ENST00000389232; = p.S4488A on NM_001036.6) | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SAFB | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- SATB2 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SCAPER | c.1695A>T p.K565N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCRN2 | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- SELL | c.800G>A p.C267Y (on ENST00000650983; = p.C254Y on NM_000655.5) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SELPLG | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 113/268 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SEPTIN5 | c.717+1G>A p.X239_splice | Splice Site (SNP) | VAF 50/206 reads (24%) | called by muse, mutect2, varscan2
- SERPINA11 | c.1036A>T p.T346S | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- SETBP1 | c.4649del p.G1550Afs*30 | Frame Shift Del (DEL) | VAF 365/558 reads (65%) | called by pindel, varscan2
- SF3B3 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- SGSM2 | c.2764G>C p.E922Q (on ENST00000426855 / NM_001098509.2; = p.E967Q on NM_014853.3) | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SHANK1 | c.1647G>T p.K549N | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SHCBP1 | c.941A>C p.Q314P | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SHCBP1L | c.1492C>A p.L498I | Missense Mutation (SNP) | VAF 89/381 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SIDT1 | c.1507G>T p.G503C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLEC7 | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 283/537 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- SLC13A3 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC16A9 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.666); called by mutect2, varscan2
- SLC37A1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SMARCC2 | c.2320-1G>A p.X774_splice | Splice Site (SNP) | VAF 25/229 reads (11%) | called by muse, mutect2, varscan2
- SMC4 | c.1579C>G p.L527V | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SMURF2 | c.646A>T p.N216Y | Missense Mutation (SNP) | VAF 67/384 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- SNED1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SPAG17 | c.4486T>C p.S1496P | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA31D1 | c.2543G>T p.G848V | Missense Mutation (SNP) | VAF 84/437 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SPATA31D1 | c.3304C>T p.Q1102* | Nonsense Mutation (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- SPEG | c.7793G>A p.G2598E | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPPL2C | c.229dup p.H77Pfs*24 | Frame Shift Ins (INS) | VAF 24/168 reads (14%) | called by mutect2, pindel, varscan2
- SPRY4 | c.205G>T p.G69C (on ENST00000434127 / NM_001127496.3; = p.G92C on NM_030964.4) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- SSBP1 | c.226+1G>T p.X76_splice | Splice Site (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2
- SSC4D | c.930G>A p.W310* | Nonsense Mutation (SNP) | VAF 45/139 reads (32%) | called by muse, mutect2, varscan2
- SSUH2 | c.1007A>T p.Q336L | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- STAG1 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 57/157 reads (36%) | called by muse, mutect2, varscan2
- STK11IP | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 81/278 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- STK3 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- STRA8 | c.732+1G>T p.X244_splice (on ENST00000275764; = p.X222_splice on NM_182489.2) | Splice Site (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- SVOPL | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SZT2 | c.7402G>T p.D2468Y (on ENST00000634258 / NM_001365999.1; = p.D2411Y on NM_015284.4) | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TAB3 | c.752A>T p.Q251L | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- TACC2 | c.6556G>T p.A2186S (on ENST00000334433; = p.A264S on NM_006997.4) | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TAF1L | c.4046T>G p.I1349S | Missense Mutation (SNP) | VAF 92/418 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TAF1L | c.1572T>A p.N524K | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- TAFA4 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 131/305 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by mutect2, varscan2
- TAP2 | c.1040C>A p.A347D | Missense Mutation (SNP) | VAF 112/541 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TBC1D9B | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 88/356 reads (25%) | called by muse, mutect2, varscan2
- TCF25 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 54/220 reads (25%) | called by mutect2, varscan2
- TESMIN | c.84C>G p.F28L | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TET3 | c.601del p.V201Wfs*28 | Frame Shift Del (DEL) | VAF 80/271 reads (30%) | called by mutect2, pindel, varscan2
- TFAP2B | c.954C>A p.H318Q | Missense Mutation (SNP) | VAF 86/509 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TFAP2D | c.473C>A p.P158Q | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- THNSL1 | c.1675A>T p.T559S | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TLR4 | c.838C>A p.L280M (on ENST00000355622 / NM_138554.5; = p.L240M on NM_003266.4) | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMC3 | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM63B | c.2261G>A p.R754K | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TMTC1 | c.2002A>G p.M668V (on ENST00000539277 / NM_001193451.2; = p.M560V on NM_175861.3) | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAPPC12 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TREML1 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 79/376 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIM49C | c.1092G>T p.E364D | Missense Mutation (SNP) | VAF 28/660 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.497); called by muse, mutect2
- TRIM77 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- TRIOBP | c.547A>G p.R183G | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TRPA1 | c.2726T>A p.F909Y | Missense Mutation (SNP) | VAF 76/314 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC1 | c.1891G>T p.V631F (on ENST00000476941 / NM_001251845.2; = p.V597F on NM_003304.4) | Missense Mutation (SNP) | VAF 22/661 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2
- TRPM5 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TRPS1 | c.2075A>T p.Y692F (on ENST00000220888 / NM_001330599.2; = p.Y705F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/290 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTLL5 | c.170G>T p.R57I | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- TTN | c.59713G>A p.G19905R (on ENST00000591111; = p.G12481R on NM_003319.4) | Missense Mutation (SNP) | VAF 25/81 reads (31%) | PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TTN | c.48830del p.P16277Qfs*37 (on ENST00000591111; = p.P8853Qfs*37 on NM_003319.4) | Frame Shift Del (DEL) | VAF 23/183 reads (13%) | called by mutect2, pindel, varscan2
- UBXN2B | c.424-2A>G p.X142_splice | Splice Site (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- UGT1A7 | c.627C>G p.N209K | Missense Mutation (SNP) | VAF 119/530 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- UNC5A | c.2096C>A p.P699H | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UNC5B | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- UNC79 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 65/620 reads (10%) | called by muse, mutect2, varscan2
- UPF2 | c.2371G>A p.V791I | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- USH2A | c.3403A>T p.R1135W | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, varscan2
- VCAN | c.6496G>A p.D2166N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- VNN2 | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VWA8 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 55/152 reads (36%) | called by muse, mutect2, varscan2
- WASHC2A | c.3298G>C p.A1100P | Missense Mutation (SNP) | VAF 397/871 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WDFY4 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 83/258 reads (32%) | called by muse, mutect2, varscan2
- WDR90 | c.3705G>T p.W1235C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WSCD1 | c.1492G>C p.V498L | Missense Mutation (SNP) | VAF 73/490 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WWC1 | c.2001-1G>T p.X667_splice | Splice Site (SNP) | VAF 41/132 reads (31%) | called by muse, mutect2, varscan2
- WWC1 | c.2001G>T p.K667N | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- XPOT | c.1810G>T p.V604F | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- YWHAE | c.339_347del p.N113_E116delinsK | In Frame Del (DEL) | VAF 13/153 reads (8%) | called by mutect2, pindel
- ZAN | c.4198T>A p.S1400T | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ZBTB4 | c.739A>T p.K247* | Nonsense Mutation (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- ZBTB7C | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- ZCCHC8 | c.1126A>T p.R376* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- ZEB2 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 58/443 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ZFHX2 | c.2264G>T p.G755V | Missense Mutation (SNP) | VAF 87/317 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX4 | c.6851G>A p.S2284N | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, varscan2
- ZFHX4 | c.9535G>T p.G3179* | Nonsense Mutation (SNP) | VAF 44/164 reads (27%) | called by muse, varscan2
- ZFHX4 | c.9536G>T p.G3179V | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.097); called by muse, varscan2
- ZFP82 | c.791G>C p.R264T | Missense Mutation (SNP) | VAF 125/236 reads (53%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFYVE26 | c.3320C>T p.P1107L | Missense Mutation (SNP) | VAF 267/627 reads (43%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ZFYVE28 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF292 | c.6941A>T p.K2314I | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF436 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF436 | c.430G>T p.G144* | Nonsense Mutation (SNP) | VAF 40/236 reads (17%) | called by mutect2, varscan2
- ZNF469 | c.6155del p.E2052Gfs*13 (on ENST00000437464; = p.E2080Gfs*13 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | called by mutect2, pindel*, varscan2
- ZNF479 | c.1563C>A p.Y521* | Nonsense Mutation (SNP) | VAF 49/174 reads (28%) | called by muse, mutect2, varscan2
- ZNF541 | c.3685G>C p.E1229Q | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- ZNF549 | c.260G>T p.G87V (on ENST00000376233 / NM_001199295.2; = p.G74V on NM_153263.2) | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF557 | c.575A>G p.K192R (on ENST00000414706 / NM_001044388.2; = p.K199R on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZNF699 | c.341G>C p.G114A | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2
- ZNF727 | c.491_503del p.K164Tfs*198 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | called by mutect2, pindel, varscan2
- ZNF804A | c.3191A>T p.K1064M | Missense Mutation (SNP) | VAF 91/308 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- ZNF841 | c.1207G>T p.G403C (on ENST00000426391 / NM_001369830.1; = p.G519C on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF850 | c.1274A>T p.E425V | Missense Mutation (SNP) | VAF 89/302 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- ABCA13 | c.723G>A p.S241= | Silent (SNP) | VAF 41/167 reads (25%) | catalogued as rs754765359, COSV70027000; called by muse, mutect2, varscan2
- ABCA7 | c.2212C>T p.L738= | Silent (SNP) | VAF 78/187 reads (42%) | catalogued as COSV99564892; called by muse, mutect2, varscan2
- ABCB5 | c.322C>T p.L108= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV99327226; called by muse, varscan2
- ACE | c.1263G>T p.G421= | Silent (SNP) | VAF 123/288 reads (43%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.324C>A p.L108= | Silent (SNP) | VAF 69/318 reads (22%) | catalogued as COSV63021603; called by muse, mutect2, varscan2
- ADAMTS5 | c.1914C>A p.G638= | Silent (SNP) | VAF 45/148 reads (30%) | called by muse, mutect2, varscan2
- ADGRG4 | c.3396A>G p.S1132= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs767050777; called by muse, mutect2, varscan2
- ANO7 | c.549C>A p.A183= (on ENST00000274979; = p.A129= on NM_001370694.2) | Silent (SNP) | VAF 93/315 reads (30%) | called by muse, mutect2, varscan2
- ANPEP | c.1443C>T p.A481= | Silent (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- ANTXRL | c.1824G>C p.P608= | Silent (SNP) | VAF 37/164 reads (23%) | called by muse, mutect2, varscan2
- APOA5 | c.376C>A p.R126= | Silent (SNP) | VAF 120/348 reads (34%) | catalogued as rs140178861; called by muse, mutect2, varscan2
- ARAP1 | c.813G>A p.E271= (on ENST00000393609 / NM_001040118.2; = p.E26= on NM_015242.4) | Silent (SNP) | VAF 31/164 reads (19%) | catalogued as rs201976946; called by muse, mutect2, varscan2
- ARHGAP12 | c.2540G>A p.*847= | Silent (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.1845G>T p.R615= (on ENST00000383472 / NM_001366230.1; = p.R456= on NM_001010000.3) | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- AXIN2 | c.1608G>A p.T536= | Silent (SNP) | VAF 63/450 reads (14%) | catalogued as rs1403070766; ClinVar: likely benign; called by muse, mutect2, varscan2
- BCLAF1 | c.2082G>T p.R694= | Silent (SNP) | VAF 48/179 reads (27%) | called by muse, mutect2, varscan2
- BTBD7 | c.1053C>T p.L351= | Silent (SNP) | VAF 62/289 reads (21%) | called by muse, mutect2, varscan2
- C12orf50 | c.142C>T p.L48= | Silent (SNP) | VAF 54/133 reads (41%) | called by muse, mutect2, varscan2
- C4orf50 | c.78G>C p.L26= (on ENST00000324058; = p.L1258= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/145 reads (43%) | called by muse, mutect2, varscan2
- CACNA1E | c.6597T>A p.A2199= (on ENST00000367573 / NM_001205293.3; = p.A2156= on NM_000721.4) | Silent (SNP) | VAF 122/338 reads (36%) | called by muse, mutect2, varscan2
- CACNA1G | c.5034G>A p.L1678= | Silent (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- CAPN9 | c.648C>T p.F216= | Silent (SNP) | VAF 63/259 reads (24%) | called by muse, mutect2, varscan2
- CCDC171 | c.1584A>G p.K528= | Silent (SNP) | VAF 53/202 reads (26%) | called by muse, mutect2, varscan2
- CCDC47 | c.96A>G p.V32= | Silent (SNP) | VAF 54/345 reads (16%) | called by muse, mutect2, varscan2
- CDH6 | c.1086G>T p.G362= | Silent (SNP) | VAF 108/383 reads (28%) | called by muse, mutect2, varscan2
- CEACAM8 | c.723C>A p.T241= | Silent (SNP) | VAF 62/120 reads (52%) | catalogued as COSV99747608; called by muse, mutect2
- CIART | c.1059C>T p.P353= | Silent (SNP) | VAF 52/125 reads (42%) | called by muse, mutect2, varscan2
- CNTN6 | c.2193G>T p.G731= | Silent (SNP) | VAF 54/143 reads (38%) | called by muse, mutect2, varscan2
- COL11A1 | c.1785G>T p.G595= | Silent (SNP) | VAF 53/220 reads (24%) | called by muse, mutect2, varscan2
- COQ7 | c.390G>T p.G130= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- CPB1 | c.831A>T p.A277= | Silent (SNP) | VAF 103/343 reads (30%) | called by muse, mutect2, varscan2
- CRACR2A | c.1347A>G p.T449= | Silent (SNP) | VAF 40/177 reads (23%) | catalogued as rs1162741222; called by muse, varscan2
- CRB1 | c.1194C>G p.V398= | Silent (SNP) | VAF 54/258 reads (21%) | catalogued as rs1211619415; called by muse, mutect2, varscan2
- DCAF6 | c.885G>T p.A295= | Silent (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2
- DCDC1 | c.3198A>T p.V1066= (on ENST00000597505 / NM_001367979.1; = p.V173= on NM_020869.3) | Silent (SNP) | VAF 55/129 reads (43%) | called by muse, mutect2, varscan2
- DCHS1 | c.4740G>T p.V1580= | Silent (SNP) | VAF 21/33 reads (64%) | called by muse, mutect2, varscan2
- DHX37 | c.2910C>T p.S970= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs115221248; called by muse, mutect2, varscan2
- DRD5 | c.219C>A p.A73= | Silent (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2
- DROSHA | c.3381A>T p.A1127= | Silent (SNP) | VAF 91/286 reads (32%) | called by muse, mutect2, varscan2
- EFS | c.1194G>T p.P398= | Silent (SNP) | VAF 63/148 reads (43%) | catalogued as rs754723164, COSV53733434; called by muse, mutect2, varscan2
- EMC1 | c.2643C>G p.R881= | Silent (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- ERVV-1 | c.879G>T p.T293= | Silent (SNP) | VAF 170/390 reads (44%) | called by muse, mutect2, varscan2
- FAM153B | c.687G>A p.Q229= (on ENST00000253490; = p.Q152= on NM_001265615.1) | Silent (SNP) | VAF 90/732 reads (12%) | called by muse, mutect2, varscan2
- FAM160A1 | c.397C>T p.L133= | Silent (SNP) | VAF 63/319 reads (20%) | called by muse, mutect2, varscan2
- FAM220A | c.69G>C p.S23= | Silent (SNP) | VAF 46/245 reads (19%) | catalogued as COSV57626236; called by muse, mutect2, varscan2
- FBRSL1 | c.2430G>T p.L810= | Silent (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- FLNC | c.7422C>T p.G2474= | Silent (SNP) | VAF 108/513 reads (21%) | catalogued as rs755019331, COSV57950427; called by muse, mutect2, varscan2
- FRAS1 | c.6447G>A p.Q2149= | Silent (SNP) | VAF 51/119 reads (43%) | catalogued as rs1189169375; called by muse, mutect2, varscan2
- FREM3 | c.6189T>C p.D2063= | Silent (SNP) | VAF 48/109 reads (44%) | called by muse, mutect2, varscan2
- FSIP2 | c.20163C>A p.T6721= | Silent (SNP) | VAF 63/257 reads (25%) | called by muse, mutect2, varscan2
- GABRB2 | c.321G>T p.L107= | Silent (SNP) | VAF 137/399 reads (34%) | called by muse, mutect2, varscan2
- GDF11 | c.783C>A p.A261= | Silent (SNP) | VAF 49/130 reads (38%) | called by muse, mutect2, varscan2
- GHR | c.1347C>A p.I449= | Silent (SNP) | VAF 92/287 reads (32%) | called by muse, mutect2, varscan2
- GLI2 | c.1857C>A p.A619= (on ENST00000361492 / NM_001374353.1; = p.A636= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 100/338 reads (30%) | called by muse, mutect2, varscan2
- GOLGA6L22 | c.1713G>C p.R571= | Silent (SNP) | VAF 117/666 reads (18%) | called by muse, varscan2
- GOLGA8M | c.966C>A p.L322= | Silent (SNP) | VAF 124/478 reads (26%) | called by mutect2, varscan2
- GPR141 | c.90C>T p.G30= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as rs368456046; called by muse, mutect2, varscan2
- GPS1 | c.582C>T p.S194= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as rs375853187; called by muse, mutect2
- GPX5 | c.597C>A p.S199= | Silent (SNP) | VAF 40/127 reads (31%) | called by muse, mutect2, varscan2
- GRID2 | c.315C>A p.L105= | Silent (SNP) | VAF 103/221 reads (47%) | catalogued as COSV99938883; called by muse, mutect2, varscan2
- HECTD4 | c.3585G>T p.L1195= | Silent (SNP) | VAF 105/265 reads (40%) | called by muse, mutect2, varscan2
- HERC1 | c.2808A>T p.P936= | Silent (SNP) | VAF 78/390 reads (20%) | called by muse, mutect2, varscan2
- HIPK2 | c.921G>A p.Q307= | Silent (SNP) | VAF 45/236 reads (19%) | called by muse, mutect2, varscan2
- HIPK3 | c.2001A>T p.R667= | Silent (SNP) | VAF 77/152 reads (51%) | called by muse, mutect2, varscan2
- HLA-G | c.57G>T p.L19= | Silent (SNP) | VAF 28/149 reads (19%) | called by muse, mutect2, varscan2
- HSPG2 | c.8329C>A p.R2777= | Silent (SNP) | VAF 154/406 reads (38%) | called by muse, mutect2, varscan2
- HYAL4 | c.456G>A p.Q152= | Silent (SNP) | VAF 32/173 reads (18%) | called by muse, mutect2, varscan2
- IER2 | c.471C>T p.A157= | Silent (SNP) | VAF 108/271 reads (40%) | called by muse, mutect2, varscan2
- IGHA2 | c.180C>A p.S60= | Silent (SNP) | VAF 165/725 reads (23%) | called by muse, mutect2, varscan2
- IGLC3 | c.168C>A p.T56= | Silent (SNP) | VAF 160/700 reads (23%) | called by mutect2, varscan2
- ITGAD | c.1377C>A p.A459= | Silent (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2
- KCNG1 | c.129G>T p.A43= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV65368166; called by muse, mutect2, varscan2
- KCNH7 | c.811C>A p.R271= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as COSV59810011; called by muse, mutect2, varscan2
- KIAA1958 | c.1575G>T p.A525= | Silent (SNP) | VAF 47/211 reads (22%) | called by muse, mutect2, varscan2
- KIF13A | c.4980A>G p.V1660= | Silent (SNP) | VAF 38/181 reads (21%) | called by muse, mutect2, varscan2
- KIF25 | c.123G>T p.A41= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV63029030; called by muse, mutect2, varscan2
- KLHL31 | c.1623G>T p.A541= | Silent (SNP) | VAF 54/206 reads (26%) | called by muse, mutect2, varscan2
- LAMA2 | c.5286G>T p.R1762= | Silent (SNP) | VAF 26/214 reads (12%) | called by muse, mutect2, varscan2
- LAMA2 | c.7011T>C p.S2337= | Silent (SNP) | VAF 116/234 reads (50%) | called by muse, mutect2, varscan2
- LILRB5 | c.486C>A p.L162= | Silent (SNP) | VAF 21/192 reads (11%) | catalogued as rs750903433, COSV60255817, COSV60260299; called by muse, mutect2, varscan2
- LRP1 | c.6741C>G p.T2247= | Silent (SNP) | VAF 138/449 reads (31%) | called by muse, mutect2, varscan2
- LRRC14B | c.1149C>A p.G383= | Silent (SNP) | VAF 168/273 reads (62%) | called by muse, mutect2, varscan2
- LRRCC1 | c.2928A>T p.A976= | Silent (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- MAGEB16 | c.210C>T p.S70= | Silent (SNP) | VAF 75/105 reads (71%) | called by muse, mutect2, varscan2
- MAGEC2 | c.315C>A p.S105= | Silent (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1257C>A p.G419= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- MAP2K3 | c.66G>A p.K22= | Silent (SNP) | VAF 146/596 reads (24%) | catalogued as rs756768384; called by muse, mutect2
- MBTPS2 | c.366C>T p.S122= | Silent (SNP) | VAF 74/129 reads (57%) | catalogued as COSV63411177; called by muse, mutect2, varscan2
- MDGA1 | c.1191C>T p.T397= | Silent (SNP) | VAF 66/275 reads (24%) | called by muse, mutect2, varscan2
- MEFV | c.2208C>A p.A736= | Silent (SNP) | VAF 130/416 reads (31%) | called by muse, mutect2, varscan2
- MFSD1 | c.585G>C p.L195= | Silent (SNP) | VAF 26/220 reads (12%) | called by muse, varscan2
- MPDZ | c.3153G>A p.G1051= | Silent (SNP) | VAF 62/301 reads (21%) | called by muse, mutect2, varscan2
- MROH8 | c.1962T>A p.P654= | Silent (SNP) | VAF 26/298 reads (9%) | called by muse, mutect2
- MYH3 | c.120G>T p.V40= | Silent (SNP) | VAF 420/713 reads (59%) | called by muse, mutect2, varscan2
- MYLK3 | c.228C>A p.G76= | Silent (SNP) | VAF 89/313 reads (28%) | called by muse, mutect2, varscan2
- MYO18B | c.6969C>A p.S2323= | Silent (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- NCKAP5 | c.1824C>A p.A608= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as COSV100490974; called by muse, mutect2, varscan2
- NDST3 | c.2571G>A p.L857= | Silent (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- NDUFAF5 | c.993A>G p.L331= | Silent (SNP) | VAF 47/180 reads (26%) | catalogued as rs200637594; called by muse, mutect2, varscan2
- NOG | c.606G>T p.V202= | Silent (SNP) | VAF 60/125 reads (48%) | called by muse, mutect2, varscan2
- NPIPB9 | c.69A>T p.P23= | Silent (SNP) | VAF 52/143 reads (36%) | called by mutect2, varscan2
- NPR3 | c.1335G>T p.R445= | Silent (SNP) | VAF 46/165 reads (28%) | called by muse, mutect2, varscan2
- NSUN2 | c.45G>T p.R15= | Silent (SNP) | VAF 38/346 reads (11%) | catalogued as rs1403773176; called by muse, mutect2, varscan2
- OR10C1 | c.111G>T p.L37= (on ENST00000622521; = p.L35= on NM_013941.3) | Silent (SNP) | VAF 49/280 reads (18%) | called by muse, mutect2, varscan2
- OR10P1 | c.187C>T p.L63= | Silent (SNP) | VAF 59/237 reads (25%) | catalogued as rs765563420, COSV100548216; called by muse, mutect2, varscan2
- OR10Q1 | c.342G>T p.T114= | Silent (SNP) | VAF 73/216 reads (34%) | catalogued as COSV57470338; called by muse, mutect2, varscan2
- OR13C4 | c.438T>C p.S146= | Silent (SNP) | VAF 34/151 reads (23%) | called by muse, mutect2, varscan2
- OR14K1 | c.738C>T p.V246= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV51720577; called by muse, mutect2, varscan2
- OR1I1 | c.435G>T p.L145= | Silent (SNP) | VAF 97/197 reads (49%) | called by muse, mutect2, varscan2
- OR3A1 | c.198G>C p.L66= | Silent (SNP) | VAF 178/300 reads (59%) | catalogued as COSV60163454; called by muse, varscan2
- OR3A3 | c.636A>C p.A212= | Silent (SNP) | VAF 72/722 reads (10%) | called by muse, mutect2
- OR5D18 | c.735C>T p.H245= | Silent (SNP) | VAF 63/206 reads (31%) | called by muse, mutect2, varscan2
198 further variants in this file (0 protein-altering or splice-affecting, 77 silent, 121 other) are not listed here.
